Somatic mutation profile of tumor specimen TCGA-MK-A84Z-01A (aliquot TCGA-MK-A84Z-01A-11D-A397-08) from TCGA case TCGA-MK-A84Z, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 74.4 years (27,185 days).
Specimen TCGA-MK-A84Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31996295-a97f-4d63-85a2-91147671027d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MK-A84Z-10A (Blood Derived Normal), aliquot TCGA-MK-A84Z-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e15afdd-dc49-4a59-9cea-f4bc58a39702

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 42/104 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs1476117427, COSV99685438; called by muse, mutect2, varscan2
- ACTL9 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100185271; called by muse, mutect2, varscan2
- AHRR | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100327085; called by muse, mutect2, varscan2
- BRDT | c.644C>A p.A215E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100746304; called by muse, mutect2, varscan2
- CPEB4 | c.641T>G p.V214G | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as COSV99436975; called by muse, mutect2, varscan2
- GIMAP6 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.445); catalogued as COSV100188202; called by muse, mutect2, varscan2
- KLF4 | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101012680, COSV65928966; called by muse, mutect2, varscan2
- SLC25A15 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100090844; called by muse, mutect2, varscan2
- SLC29A1 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100505741; called by muse, mutect2, varscan2
- TAOK3 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as rs763387926, COSV101183515; called by muse, mutect2, varscan2
- THUMPD3 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs764885828, COSV61506929; called by muse, mutect2, varscan2
- RPS6KA4 | c.1074del p.Y359Tfs*16 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- CASZ1 | c.1968C>T p.Y656= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs779789610, COSV59733410; called by muse, mutect2, varscan2
- ERMARD | c.561C>T p.N187= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as rs750048908, COSV100824792; called by muse, mutect2, varscan2
- GRIA1 | c.2367C>T p.S789= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs768117586, COSV99599374; called by muse, mutect2, varscan2
- PPP1R3A | c.1701C>T p.S567= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs747107675, COSV99492659; called by muse, mutect2, varscan2
